Somatic mutation profile of tumor specimen 0DPCXV from CCDI case PBCBCH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Tissue or organ of origin: Head of pancreas; Age at diagnosis: 17.2 years (6,295 days).
Specimen 0DPCXV: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7d02571-0b97-42cd-9897-8e5535ab34ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPCXO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c5dd0f1-c629-4bff-bcc7-3dd3c1e5d046

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'UTR 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAT2A | c.989T>G p.I330S | Missense Mutation (SNP) | VAF 20/788 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2
- TBC1D3I | c.1380G>C p.T460= | Silent (SNP) | VAF 4/250 reads (2%) | catalogued as rs1295420890; called by muse, mutect2
- NAA25 | c.*64A>G | 3'UTR (SNP) | VAF 11/305 reads (4%) | called by muse, mutect2
- PPFIA3 | c.*14-20C>T | Intron (SNP) | VAF 66/145 reads (46%) | called by muse, mutect2, varscan2
